TARGET case TARGET-15-SJMPAL012419 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07a7c5e1-a506-4a8c-a6a2-4a02c11197cb

Demographics
Sex at birth: male; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.4 years (5,973 days); Year of diagnosis: 2007; Days to last follow up: 1,229 days (3.4 years).

Follow-up (1 entry)
- Days to follow up: 1,229 days (3.4 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,229; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 43 ×10³/µL.

Biospecimens (5 samples)
- Sample TARGET-15-SJMPAL012419-04A.1: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Samples TARGET-15-SJMPAL012419-09A, TARGET-15-SJMPAL012419-09A.1, TARGET-15-SJMPAL012419-09B (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012419-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 1229
- Protocol: St. Jude
- WBC at Diagnosis: 43
- Initial Therapy: AML
- Karyotype: 46,xy,del(1)(q24q32),add(7)(p13),del(17)(p11.2)[13]/46,xy[7]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
- WHO RL1: B/M
